Surgical pathology report (de-identified scan), TCGA case TCGA-BB-7872, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-BB-7872-01A (Primary Tumor).

[page 1 of 10]
=====

INTERPRETATION AND DIAGNOSIS:

1) ANTERIOR DEEP TONGUE (EXCISION):

NEGATIVE FOR TUMOR.

2) FLOOR OF MOUTH MUCOSA (EXCISION):

NEGATIVE FOR TUMOR.

3) ALVEOLAR MARGIN (EXCISION):

NEGATIVE FOR TUMOR.

4) RIGHT HARD PALATE (EXCISION):

NEGATIVE FOR TUMOR.

5) RIGHT MEDIAL PHARYNX (EXCISION):

BENIGN FIBROCONNECTIVE AND MUSCULAR TISSUE. NEGATIVE FOR TUMOR.

6) BASE OF TONGUE (EXCISION):

NEGATIVE FOR TUMOR.

7) ANTERIOR TONGUE (EXCISION):

SQUAMOUS MUCOSA WITH MILD TO MODERATE DYSPLASIA. NEGATIVE FOR
INVASIVE CARCINOMA.

NOTE: The dysplasia is best appreciated on the frozen section
slides.

8) RIGHT BUCCAL MUCOSA (EXCISION):

NEGATIVE FOR TUMOR.

9) RIGHT PTERYGOID (EXCISION):

BENIGN MUSCULAR TISSUE, NEGATIVE FOR TUMOR.

10) RIGHT SOFT PALATE (EXCISION):

NEGATIVE FOR TUMOR.

11) DEEP GLOSSO-TONSILLAR SULCUS (EXCISION):

NEGATIVE FOR TUMOR.

FINAL DOCUMENT

[page 2 of 10]
12) LEFT NECK, LEVEL 2 (DISSECTION):

ONE (1) BENIGN LYMPH NODE.

13) RIGHT NECK, LEVEL 1 (DISSECTION):

BENIGN SALIVARY GLAND AND FOUR (4) BENIGN LYMPH NODES.

14) LEFT NECK, LEVEL 2 (DISSECTION):

SIXTEEN (16) BENIGN LYMPH NODES.

15) RIGHT NECK, LEVEL 2 (DISSECTION):

TWENTY-THREE (23) BENIGN LYMPH NODES.

16) LEFT NECK, LEVEL 3 (DISSECTION):

TEN (10) BENIGN LYMPH NODES.

17) RIGHT NECK, LEVEL 3 (DISSECTION):

ELEVEN (11) LYMPH NODES, NEGATIVE FOR TUMOR.

18) RIGHT NECK, LEVEL 4 (DISSECTION):

NINE (9) BENIGN LYMPH NODES.

19) RIGHT PARTIAL GLOSSECTOMY PARTIAL PHARYNGECTOMY:

SPECIMEN TYPE:

PARTIAL GLOSSECTOMY, PARTIAL PHARYNGECTOMY

TUMOR SITE:

ORAL CAVITY, PHARYNX

TUMOR SIZE:

TWO TUMOR FOCI ARE PRESENT, MEASURING 1.4 CM AND 1.0 CM. THE GREATEST DEPTH OF INVASION IS 0.7 CM.

HISTOLOGIC TYPE:

SQUAMOUS CELL CARCINOMA.

HISTOLOGIC GRADE:

G3: POORLY DIFFERENTIATED

EXTENT OF INVASION (7th Edition AJCC):

PRIMARY TUMOR (pT):

pT1: Tumor 2 cm or less in greatest dimension

REGIONAL LYMPH NODES (pN):

pN0: NO REGIONAL LYMPH NODE METASTASIS

All 74 lymph nodes examined are negative for tumor (See part 12-18).

MARGINS:

TUMOR IS PRESENT AT THE BUCCAL MARGIN, AND IS 1 MM FROM THE OPPOSITE MARGIN. THE DEEP MARGIN IS NEGATIVE FOR TUMOR. MILD DYSPLASIA IS PRESENT AT THE ANTERIOR LATERAL TONGUE MARGIN OF THE SPECIMEN (SEE PARTS 1-11 FOR ADDITIONAL MARGINS).

FINAL DOCUMENT

[page 3 of 10]
VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION:
INDETERMINATE.

PERINEURAL INVASION:
PRESENT.

NOTE: An immunohistochemical stain for p16 shows focal positivity.
In situ hybridization for high risk HPV is negative. This case was
shown at the daily quality assurance conference.

[REDACTED]

*Electronic signature by which I attest that the above diagnosis is
based upon my personal examination of the slides (and / or other
material indicated in the diagnosis), and that I have reviewed and
approved this report.

=====
Clinical History:
NOT PROVIDED

GROSS DESCRIPTION

PART #1: FS: ANTERIOR DEEP TONGUE [REDACTED]

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists [REDACTED]

Anterior deep tongue: Negative for tumor.

Dictated by [REDACTED]

The specimen is received fresh for frozen section evaluation in a
container labeled with the patient's name [REDACTED] and designated
'Anterior deep tongue' is a single 1.1 x 0.7 x 0.4 cm portion of
red-brown irregular shaped soft tissue. Submitted in total for frozen
section evaluation.

SUMMARY OF SECTIONS

1 - FSC - 1 (ANTERIOR DEEP TONGUE)
1 - TOTAL - 1

PART #2: FS: FLOOR OF MOUTH MUCOSA [REDACTED]

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists [REDACTED]

Floor of mouth mucosa: Negative for tumor.

Dictated by [REDACTED]

The specimen is received fresh for frozen section evaluation in a
container labeled with the patient's name [REDACTED] and designated

[REDACTED] FINAL DOCUMENT [REDACTED]

[page 4 of 10]
'Floor of mouth mucosa' is a single 0.8 x 0.5 x 0.4 cm portion of red-brown irregular shaped soft tissue. Submitted in total for frozen section evaluation.

SUMMARY OF SECTIONS

1 - FSC - 1 (FLOOR OF MOUTH MUCOSA)
1 - TOTAL - 1

PART #3: FS: ALVEOLAR MARGIN [REDACTED]

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists [REDACTED]

Alveolar margin: Negative for tumor.

Dictated by [REDACTED]

The specimen is received fresh for frozen section evaluation in a container labeled with the patient's name [REDACTED] and designated 'Alveolar margin' are two portions of red-tan irregular shaped soft tissue measuring 0.4 x 0.3 x 0.2 cm and 0.3 x 0.3 x 0.2 cm. Submitted in total for frozen section evaluation.

SUMMARY OF SECTIONS

1 - FSC - 2 (ALVEOLAR MARGIN)
1 - TOTAL - 2

PART #4: FS: RIGHT HARD PALATE [REDACTED]

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists [REDACTED]

Right hard palate: Negative for tumor.

Dictated by [REDACTED]

The specimen is received fresh for frozen section evaluation labeled with the patient's name [REDACTED] and designated 'Right hard palate' is a single 0.9 x 0.7 x 0.4 cm irregular shaped soft tissue. Submitted in total for frozen section evaluation.

SUMMARY OF SECTIONS

1 - FSC - 1 (RIGHT HARD PALATE)
1 - TOTAL - 1

PART #5: FS: RIGHT MEDIAL PHARYNX [REDACTED]

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

[REDACTED] FINAL DOCUMENT [REDACTED]

[page 5 of 10]
Staff Pathologist: [REDACTED]
Other Pathologists: [REDACTED]

Right medial pharynx: Negative for tumor.

Dictated by [REDACTED]

The specimen is received fresh for frozen section evaluation in a container labeled with the patient's name [REDACTED] and designated 'Right medial pharynx' is a single 0.9 x 0.6 x 0.5 cm portion of red-tan irregular shaped soft tissue. Submitted in total for frozen section evaluation.

SUMMARY OF SECTIONS

1 - FSC - 1 (RIGHT MEDIAL PHARYNX)
1 - TOTAL - 1

PART #6: FS: BASE OF TONGUE [REDACTED]
Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]
Other Pathologists: [REDACTED]

Base of tongue: Negative for tumor.

Dictated by [REDACTED]

The specimen is received fresh for frozen section labeled with the patient's name [REDACTED] and designated 'Base of tongue.' It consists of a 0.6 x 0.3 x 0.3 cm of red-tan soft tissue. It is entirely submitted for frozen section.

SUMMARY OF SECTIONS

1 - FSC - 1
1 - TOTAL - 1

PART #7: FS: ANTERIOR TONGUE [REDACTED]
Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]
Other Pathologists: [REDACTED]

Anterior tongue: Mild to moderate squamous dysplasia.

Dictated by [REDACTED]

The specimen is received fresh for frozen section labeled with the patient's name [REDACTED] and designated 'Anterior tongue.' It consists of a 0.6 x 0.5 x 0.3 cm fragment of red-pink soft tissue. It

[REDACTED] FINAL DOCUMENT [REDACTED]

[page 6 of 10]
is entirely submitted for frozen section.

SUMMARY OF SECTIONS

1 - FSC - 1
1 - TOTAL - 1

PART #8: FS: RIGHT BUCCAL MUCOSA

Resident Pathologist:

FROZEN SECTION DIAGNOSIS:

Staff Pathologist:

Other Pathologists

Right buccal mucosa: Negative for tumor.

Dictated by

The specimen is received fresh for frozen section labeled with the patient's name and designated 'Right buccal mucosa.' It consists of a 1 x 0.8 x 0.4 cm fragment of tan soft tissue. It is entirely submitted for frozen section.

SUMMARY OF SECTIONS

1 - FSC - 1
1 - TOTAL - 1

PART #9: FS: RIGHT PTERYGOID

Resident Pathologist:

FROZEN SECTION DIAGNOSIS:

Staff Pathologist:

Other Pathologists

Right pterygoid: Negative for tumor.

Dictated by

The specimen is received fresh labeled with the patient's name and designated 'Right pterygoid.' The specimen consists of one piece of red-tan soft tissue measuring 1 x 0.3 x 0.2 cm. The specimen is entirely submitted for frozen section.

SUMMARY OF SECTIONS

1 - FSC - 1 (TISSUE)
1 - TOTAL - 1

PART #10: FS: RIGHT SOFT PALATE

Resident Pathologist:

FROZEN SECTION DIAGNOSIS:

Staff Pathologist:

Other Pathologists

FINAL DOCUMENT

[page 7 of 10]
Right soft palate: Negative for tumor.

Dictated by [REDACTED]

The specimen is received fresh labeled with the patient's name [REDACTED] and designated 'Right soft palate.' The specimen consists of one piece of red-tan soft tissue measuring 0.8 x 0.2 x 0.2 cm. The specimen is entirely submitted for frozen section.

SUMMARY OF SECTIONS

1 - FSC - 1
1 - TOTAL - 1

PART #11: FS: DEEP GLOSSO-TONSILLAR SULCUS [REDACTED]

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists [REDACTED]

Deep glosso-tonsillar sulcus: Negative for tumor.

Dictated by [REDACTED]

The specimen is received fresh for frozen section labeled with the patient's name [REDACTED] and designated 'Deep glosso-tonsillar sulcus.' The specimen consists of one fragment of red-tan soft tissue measuring 0.8 x 0.5 x 0.3 cm. The specimen is entirely submitted for frozen.

SUMMARY OF SECTIONS

1 - FSC - 1 (DEEP GLOSSOTONSILLAR SULCUS)
1 - TOTAL - 1

PART #12: FS: LEFT LEVEL 2 LYMPH NODE [REDACTED]

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists [REDACTED]

Left level 2 lymph node: One lymph node, negative for tumor.

Dictated by [REDACTED]

The specimen is received fresh for frozen section labeled with the patient's name [REDACTED] and designated 'Left level 2 lymph node.' The specimen consists of two fragments of yellow-tan soft tissue measuring 2.0 x 0.6 x 0.4 cm in aggregate. The larger portion of soft tissue is bisected to reveal one possible lymph node. The specimen is entirely submitted for frozen.

SUMMARY OF SECTIONS

1 - FSC - 3 (LEFT LEVEL 2 LYMPH NODE)

[REDACTED] FINAL DOCUMENT [REDACTED]

[page 8 of 10]
1 - TOTAL - 3

PART #13: RIGHT NECK DISSECTION LEVEL 1

Resident Pathologist:

Dictated by

The specimen is received fresh labeled with the patient's name and designated 'Right neck dissection level 1.' The specimen consists of a portion of fibrofatty tissue and a portion of salivary gland. The salivary gland measures 5.5 x 2.5 x 1.5 cm. Within the soft tissue three possible lymph nodes are identified ranging in size from 0.7 up to 1.1 cm. The salivary gland is sectioned to reveal no masses or nodules. Representative sections are submitted from the salivary gland, the rest of the tissue is entirely submitted.

SUMMARY OF SECTIONS

- 1 - A - 1 (ONE POSSIBLE LYMPH NODE)
- 2 - B,C - 2 EACH (ONE LYMPH NODE BISECTED EACH)
- 1 - D - M (REMAINDER OF SOFT TISSUE)
- 3 - E-G - 1 EACH (SALIVARY GLAND)
- 7 - TOTAL - M

PART #14: LEFT NECK DISSECTION LEVEL 2

Resident Pathologist:

Dictated by

The specimen is received fresh labeled with the patient's name and designated 'Left neck dissection level 2.' The specimen consists of a portion of fibrofatty tissue within 16 possible lymph node are identified ranging in size from 0.3 up to 3.5 cm in greatest dimension. The specimen is entirely submitted.

SUMMARY OF SECTIONS

- 2 - A,B - 4 EACH (FOUR POSSIBLE LYMPH NODES)
- 1 - C - 3 (THREE POSSIBLE LYMPH NODES)
- 1 - D - 2 (ONE LYMPH NODE BISECTED)
- 1 - E - 2 (ONE LYMPH NODE BISECTED)
- 2 - F,G - 2 EACH (ONE LYMPH NODE BISECTED)
- 1 - H - 2 (ONE LYMPH NODE SECTIONED)
- 2 - I,G - M EACH (REMAINDER OF SOFT TISSUE)
- 10 - TOTAL - M

PART #15: RIGHT NECK DISSECTION LEVEL 2

Resident Pathologist:

Dictated by

The specimen is received fresh labeled with the patient's name and designated 'Right neck dissection level 2.' The specimen consists of a portion of fibrofatty tissue within which 14 possible lymph nodes are identified ranging in size from 0.4 up to 2.3 cm in greatest dimension. The specimen is entirely submitted.

SUMMARY OF SECTIONS

FINAL DOCUMENT

[page 9 of 10]
2 - A,B - 4 EACH (FOUR POSSIBLE LYMPH NODES)
2 - C,D - 2 EACH (TWO POSSIBLE LYMPH NODES)
2 - E,F - 2 EACH (ONE LYMPH NODE BISECTED EACH)
5 - G-K - M EACH (REMAINDER OF SOFT TISSUE)
11 - TOTAL - M

PART #16: LEFT NECK DISSECTION LEVEL 3

Resident Pathologist:

Dictated by

The specimen is received fresh labeled with the patient's name and designated 'Left neck dissection level 3.' The specimen consists of a portion of fibrofatty tissue within which eight possible lymph nodes are identified ranging in size from 0.3 up to 2.0 cm in greatest dimension. The specimen is entirely submitted.

SUMMARY OF SECTIONS

1 - A - 4 (FOUR POSSIBLE LYMPH NODES)
4 - B-E - 2 EACH (ONE LYMPH NODE BISECTED)
1 - F - M (REMAINDER OF SPECIMEN)
6 - TOTAL - M

PART #17: RIGHT NECK DISSECTION LEVEL 3

Resident Pathologist:

Dictated by

The specimen is received fresh labeled with the patient's name and designated 'Right neck dissection level 3.' The specimen consists of a portion of fibrofatty tissue within which twelve possible lymph nodes are identified ranging in size from 0.2 up to 1.6 cm in greatest dimension. The specimen is entirely submitted.

SUMMARY OF SECTIONS

2 - A,B - 4 (FOUR POSSIBLE LYMPH NODES EACH)
1 - C - 1 (ONE LYMPH NODE)
1 - D - 2 (TWO LYMPH NODES)
1 - E - 2 (ONE LYMPH NODE BISECTED)
1 - F - M (REMAINDER OF TISSUE)
6 - TOTAL - M

PART #18: RIGHT NECK DISSECTION LEVEL 4

Resident Pathologist:

Dictated by

The specimen is received fresh labeled with the patient's name and designated 'Right neck dissection level 4.' The specimen consists of a portion of fibrofatty tissue with seven possible lymph nodes identified ranging in size from 0.3 up to 1.0 cm in greatest dimensions. Additionally, multiple tiny possible lymph nodes measuring less than 3 mm are identified. The specimen is entirely submitted.

FINAL DOCUMENT

[page 10 of 10]
SUMMARY OF SECTIONS

2 - A,B - 3 EACH (THREE POSSIBLE LYMPH NODES)
1 - C - 2 (ONE LYMPH NODE BISECTED)
1 - D - 1 (MULTIPLE SMALL LYMPH NODES)
2 - E,F - M EACH (REMAINDER OF FIBROADIPOSE TISSUE)
6 - TOTAL - M

PART #19: RIGHT PARTIAL GLOSSECTOMY PARTIAL PHARYNGECTOMY

Resident Pathologist:

Dictated by:

The specimen is received fresh labeled with the patient's name, and designated 'right partial glossectomy partial pharyngectomy'. The specimen consists of a portion of mucosa and underlying soft tissue. The specimen has been oriented with a single stitch marking the anterior lateral tongue, and a double stitch marking the right medial soft palate. The specimen measures 7.9 cm in length x 1.8 x 1.1 cm. A photograph is taken from the specimen. The specimen is inked as follows: superior-blue, inferior-green, deep-black. The specimen is serially sectioned from the area of the single suture to the double suture and entirely submitted. The sections are designated on the photograph.

SUMMARY OF SECTIONS:

1 -A - 1
1 -B - 3
1 -C - 2
1 -D - 3
2 - E-F - 3 EA.
1 - G - 2
2 - H-I - 1 EA.
3 - J-L - 2 EA.
1 - M - 1
13 -TOTAL - M

Other Surgical Pathology Specimens known to the computer:

(End of Report)

Note: This note provides information pertaining only to a specific event. A more detailed medical history is available in the Medical Record.

FINAL DOCUMENT

Source: NCI Genomic Data Commons file 4634ec57-d2e2-4471-a773-d3f08e147f79 (TCGA-BB-7872.58A435B1-5A53-49C5-B938-4B917D5D6C24.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).